Surgical pathology report (de-identified scan), TCGA case TCGA-DV-A4W0, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-A4W0-01A (Primary Tumor).

[page 1 of 3]
MEDICAL RECORD**Surgical Pathology Report**UUID: 7511A809-4B7C-4A77-9D6F-D2AF59441E84

**Surgical Pathology Report**

PATIENT:		MRN:	
ACCOUNT#:		RECEIVED DATE:	
DOB:		PROCEDURE DATE:	
AGE:	SEX: M	SIGN-OUT DATE:	
ATTENDING:		LOCATION:	
REQUESTING:			
CONTACT NO:		ROOM:	
COPIES TO:			

DIAGNOSIS:

1. Adrenal, left (excision): Adrenal, no tumor seen.
2. Kidney "left upper pole tumor" (excision):
- Renal cell carcinoma, clear cell type, Furhman nuclear grade III; tumor permeates the capsule but does not extend to the inked margin.
- Adrenal gland.
3. Kidney, "inferior tumor" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II with extensive fibrosis.
4. "Gerota's cover over largest tumor" (excision): Fibroadipose tissue, no tumor seen.

NOTE:

CLINICAL INFORMATION: Allocate Order to Protocol: Brief Clinical History year
old male with bilateral renal masses for left partial nephrectomy
Specimen Taken For Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: renal mass left Post-Operative Diagnosis:
renal mass left Operative Findings: left renal masses

ICD-0-3

carcinoma, clear cell 8310/3

Site: Kidney, NOS 64.9

lw
10/26/12

- SPECIMENS SUBMITTED:** 1. ADRENAL GLAND, LEFT
2. TUMOR, Left upper pole
3. TUMOR, Inferior
4. TUMOR, Gerotas over the largest

Patient Identification

Surgical Pathology Report

[page 2 of 3]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Name:
MRN:

Accession No.:

GROSS DESCRIPTION: Received are 4 formalin-filled containers labeled with the patient's name, medical record number, and further specified as follows:

1. "Left adrenal". The specimen consists of a tan/red soft tissue fragment measuring 1.2 x 0.6 x 0.5 cm. The specimen is serially sectioned and entirely submitted in white cassette labeled #1 for permanent processing.

2. "Left upper pole tumor". The specimen consists of an 82.9 gram piece of red/tan tissue measuring 14.4 x 8.9 x 4.8 cm. It has a tan/brown surface grossly consistent with renal parenchyma at the lower portion of the specimen. There is an ill-defined nodular density, measuring 6.5 cm in greatest dimension by external examination. There is attached fat and fascia. No renal vessels or ureter is identified grossly. There is a thin rim of golden yellow tissue which appears grossly to be adrenal on one aspect of the specimen. In the lower portion of the specimen, there is additional nodular density measuring 1.5 cm on external examination. The specimen is bisected to reveal a multinodular yellow/tan cut surface with areas of cysts and hemorrhage, maximum 6.5 cm in dimension. Multiple fragments measuring 4.0 x 1.0 x 0.4 cm in aggregate are procured from the center of the lesion for . The procurement was done by . The specimen is sent to Surgical Pathology and matches the above description. The specimen is serially sectioned to reveal a nodule measuring 1.5 x 1.2 cm inferior to the larger nodule and a smaller partly hemorrhagic nodule measuring 1.1 x 1.3 cm that corresponds to the firm area in the lower portion of the specimen. Representative sections are taken and submitted in white cassettes labeled #2 for permanent processing as follows: 2A-2E representative sections of the larger tumor nodule, 2F section from the hemorrhagic nodule at the lower portion of the specimen, 2G section of the second nodule with renal margin, 2H normal renal parenchyma, 2I capsule and adrenal.

3. "Inferior tumor". The specimen consists of a nodular white/yellow tissue with attached piece of fat measuring 3.4 x 2.1 x 2.1 cm and fat measuring 4.3 x 3.2 x 1.1 cm. A very thin rim of brown tissue, resembling renal parenchyma is seen at one side of the nodule. The nodule is inked in black and bisected to reveal a multicystic fluid-filled cavity. 0.4 x 0.4 x 0.2 cm specimen is procured for . The procurement was done by . The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The specimen is serially sectioned and representative sections submitted in white cassettes labeled #3 for permanent processing as follows: 3A-3C representative sections of tumor with attached renal parenchyma, 3D tumor with attached fat.

4. "Gerota's cover the largest tumor". The specimen consists of a tan/red soft tissue fragment grossly resembling fat measuring 15.0 x 4.5 x 0.6 cm in the largest dimension. The specimen is serially sectioned and representative sections are submitted in white cassette labeled #4 for permanent processing as follows: 4A-4E representative sections from the fat.

Gross dictated by

Patient Identification

Surgical Pathology Report

[page 3 of 3]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

Name:
MRN:

Accession No.:

No consultants

Prior Malignancy History	KIRC-Right	✓
Dual/Synchronous Primary	Noted	✓

Patient Identification

Surgical Pathology Report

Source: NCI Genomic Data Commons file fecf133e-925b-4cc6-b515-a4592e187d20 (TCGA-DV-A4W0.7511A809-4B7C-4A77-9D6F-D2AF59441E84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).